Gene-level copy-number profile of tumor specimen ALCH-B1UT-TTP1-A from ALCHEMIST case ALCH-B1UT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.5 years (24,666 days).
Specimen ALCH-B1UT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 972b2a85-2327-439a-bfa1-244e2d96c284.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1UT-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/885d0b86-2b24-43fa-9892-a065fd3e947b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 178; copy number 1: 4,332; copy number 2: 53,195; copy number 3: 487; copy number 4: 193; copy number 5: 7; copy number 6: 2; copy number 11: 3; copy number 16: 1.

Homozygous deletions (total copy number 0; autosomes only): 178 genes in 47 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:109,249,539–109,275,751, 1 gene: CELSR2.
- chr1:235,361,153–235,362,540, 1 gene: AL357556.1.
- chr2:130,139,287–130,182,750, 2 genes (within-gene range 0–2): CCDC74B, SMPD4.
- chr2:131,492,813–131,649,615, 7 genes: SMPD4BP, CCDC74A, MED15P4, POTEKP, RNU6-617P, LINC01087, GRAMD4P8.
- chr2:232,349,754–232,487,834, 11 genes: ECEL1P3, AC068134.3, ALPP, AC068134.1, ECEL1P2, ALPG, ECEL1P1, AC068134.2, DIS3L2P1, ALPI, ECEL1.
- chr2:238,100,340–238,168,900, 4 genes: ESPNL, KLHL30, KLHL30-AS1, ERFE.
- chr4:3,441,968–3,501,473, 2 genes: HGFAC, DOK7.
- chr4:8,846,076–8,871,839, 2 genes: HMX1, AC116612.1.
- chr5:466,124–524,449, 3 genes (within-gene range 0–2): PP7080, SLC9A3, SLC9A3-AS1.
- chr7:102,264,706–102,321,711, 3 genes (within-gene range 0–1): AC005088.1, SH2B2, MIR4285.
- chr7:129,756,266–129,785,185, 5 genes (within-gene range 0–2): RNA5SP244, MIR182, MIR96, MIR183, AC084864.1.
- chr9:128,392,007–128,437,351, 5 genes (within-gene range 0–2): AL359091.1, MIR219A2, MIR219B, CERCAM, AL359091.4.
- chr9:130,892,707–130,945,520, 3 genes: QRFP, FIBCD1, AL161733.1.
- chr10:48,976,554–49,018,897, 3 genes (within-gene range 0–2): AC060234.2, AC060234.1, MIR4294.
- chr11:2,129,112–2,173,138, 9 genes: IGF2, AC132217.2, AC132217.1, INS-IGF2, MIR483, IGF2-AS, INS, TH, MIR4686.
- chr11:63,985,853–64,001,811, 1 gene (within-gene range 0–2): OTUB1.
- chr11:77,066,961–77,215,241, 3 genes: CAPN5, OMP, MYO7A.
- chr15:25,169,337–25,241,827, 40 genes (within-gene range 0–2): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39.
- chr15:41,825,099–41,894,053, 7 genes (within-gene range 0–2): AC020659.2, JMJD7, JMJD7-PLA2G4B, PLA2G4B, SPTBN5, RNA5SP393, MIR4310.
- chr15:93,035,273–93,089,204, 2 genes: RGMA, YBX2P2.
- chr16:15,643,267–15,734,691, 4 genes (within-gene range 0–2): NDE1, MIR484, AC026401.2, AC026401.3.
- chr16:15,726,674–15,741,791, 2 genes (within-gene range 0–2): AF001548.2, AF001548.1.
- chr16:67,199,111–67,206,849, 3 genes: ELMO3, MIR328, AC040160.2.
- chr16:75,204,103–75,228,197, 3 genes (within-gene range 0–2): CTRB2, CTRB1, AC009078.2.
- chr16:89,873,570–90,019,890, 10 genes (within-gene range 0–2): TCF25, AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3, DEF8, CENPBD1, AFG3L1P, DBNDD1.
- chr17:18,943,999–18,944,073, 1 gene: AC090286.2.
- chr17:18,951,625–18,954,149, 1 gene (within-gene range 0–2): AC090286.1.
- chr17:34,574,123–34,579,369, 1 gene: C17orf102.
- chr17:63,454,993–63,521,848, 5 genes: AC005828.5, PPIAP55, ACE, AC113554.1, ACE3P.
- chr17:66,964,707–67,033,398, 3 genes: CACNG4, AC005544.1, AC005544.2.
- chr17:81,833,492–81,860,624, 3 genes: PPP1R27, P4HB, AC145207.3.
- chr17:82,050,691–82,098,294, 3 genes (within-gene range 0–1): GPS1, DUS1L, FASN.
- chr18:59,220,158–59,274,086, 2 genes: GRP, RAX.
- chr19:34,481,758–34,512,304, 1 gene: WTIP.
- chr19:38,184,376–38,229,714, 4 genes (within-gene range 0–2): AC011479.3, AC011479.2, RN7SL663P, DPF1.
- chr20:435,480–462,543, 2 genes: TBC1D20, Y_RNA.
- chr21:36,698,773–36,749,917, 2 genes: AP000697.1, SIM2.
- chr22:23,390,606–23,402,726, 2 genes: ZDHHC8P1, AP000344.2.
- chr22:48,489,553–48,850,912, 3 genes (within-gene range 0–2): TAFA5, Z84468.1, MIR4535.
- chr22:50,217,689–50,251,405, 2 genes (within-gene range 0–2): TUBGCP6, HDAC10.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 13 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:1,056,250–1,113,564, 2 genes, copy number 6: RNF212, AC092535.3.
- chr8:143,566,192–143,578,649, 3 genes, copy number 11 (within-gene range 2–11): MROH6, AC067930.4, NAPRT.
- chr12:124,911,604–124,935,895, 3 genes, copy number 5: UBC, MIR5188, RPL22P19.
- chr14:77,024,543–77,031,572, 2 genes, copy number 5: IRF2BPL, AC007686.3.
- chr16:89,217,703–89,237,141, 2 genes, copy number 5: ZNF778, AC009113.2.
- chr21:43,446,601–43,453,902, 1 gene, copy number 16: LINC00319.

Autosomal genes at a single copy (total copy number 1): 3,134. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
